Somatic mutation profile of tumor specimen C3L-01291-35 (aliquot CPT0099810002) from CPTAC case C3L-01291, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.4 years (25,353 days).
Specimen C3L-01291-35: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64597054-fb2e-4712-8192-3a2b820ed921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01291-50 (Buccal Cell Normal), aliquot CPT0099850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ca69082-3c95-404d-86d8-44097041fb44

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Translation Start Site 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP39 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.332); catalogued as rs369269697; called by muse, mutect2, varscan2
- DIP2C | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1326148371, COSV55163625; called by muse, mutect2
- FARP2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs748526286; called by muse, varscan2
- KSR2 | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563602140, COSV56674686; called by muse, mutect2, varscan2
- VWA5B2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs558302255; called by muse, mutect2, varscan2
- MAU2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 148/307 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NCOA5 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 130/251 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SMC1A | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 136/225 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMXL3 | c.447G>A p.K149= | Silent (SNP) | VAF 49/73 reads (67%) | called by muse, mutect2, varscan2
- NDUFA9 | c.897-134G>A | Intron (SNP) | VAF 33/110 reads (30%) | called by mutect2, varscan2
